MMRF case MMRF_1830 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4b61e506-f40b-471b-8cbc-daa73cbade18

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.5 years (25,372 days); ISS stage: III; Days to last known disease status: 1,102 days (3.0 years); Days to last follow up: 1,102 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 862 days (2.4 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days.
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 863 days (2.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 4.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 61.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.067 mg/dL; Immunoglobulin G 50.3 g/L; Immunoglobulin A 0.04 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 6.3 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.5 mmol/L; Albumin 37 g/L; Total Protein 9.5 g/dL; Glucose 4.9 mmol/L; C-Reactive Protein 0.05 mg/dL.
- Day 81 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.505 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.096 mg/dL; Immunoglobulin G 3.38 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 5.17 mmol/L.
- Day 149 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.879 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.575 mg/dL; Immunoglobulin G 2.09 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 135 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 5.28 mmol/L.
- Day 246 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.838 mg/dL; Immunoglobulin G 2.21 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 152 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 5.1 g/dL; Glucose 4.73 mmol/L.
- Day 338: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.486 mg/dL; Immunoglobulin G 2.01 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 84 ×10⁹/L; Creatinine 142 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 5.39 mmol/L.
- Day 457 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.996 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.812 mg/dL; Immunoglobulin G 2.7 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.82 µkat/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 5.39 mmol/L.
- Day 542 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.748 mg/dL; Immunoglobulin G 2.19 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 3.43 µg/mL; Lactate Dehydrogenase 3.87 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 4.95 mmol/L.
- Day 639 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.784 mg/dL; Immunoglobulin G 2 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 140 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 5.5 g/dL; Glucose 5.83 mmol/L.
- Day 751 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.879 mg/dL; Immunoglobulin G 2.63 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 5.2 g/dL; Glucose 5.61 mmol/L.
- Day 835: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.833 mg/dL; Immunoglobulin G 1.89 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 134 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 5.5 g/dL; Glucose 5.89 mmol/L.
- Day 933 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.709 mg/dL; Immunoglobulin G 1.8 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 182 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 5.1 g/dL; Glucose 5.56 mmol/L.
- Day 981: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.775 mg/dL; Immunoglobulin G 2.04 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.05 mmol/L; Albumin 35 g/L; Total Protein 5.4 g/dL; Glucose 6.05 mmol/L.
- Day 1,102 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.751 mg/dL; Immunoglobulin G 2.28 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 81 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 5.8 g/dL; Glucose 5.61 mmol/L.

Other clinical attributes
- Day 1: Weight: 79 kg; Height: 152 cm.

Biospecimens (2 samples)
- Sample MMRF_1830_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1830_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
